Somatic mutation profile of cancer-model specimen HCM-CSHL-0438-C18-85A (3D Organoid, passage 7; aliquot HCM-CSHL-0438-C18-85A-01D-A82H-36), derived from the primary tumor of HCMI case HCM-CSHL-0438-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; Tumor grade: G2.
Specimen HCM-CSHL-0438-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 7.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1c4a3801-a492-4c06-aaa4-52b428918a0b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0438-C18-10A (Blood Derived Normal), aliquot HCM-CSHL-0438-C18-10A-01D-A82H-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3b6b642c-7f0b-42f0-9970-c2dbcd99f9d5

The open-access MAF lists 141 somatic variants for this specimen: 105 protein-altering or splice-affecting, 32 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 94, Silent 32, Nonsense Mutation 4, Frame Shift Del 4, Intron 3, Splice Region 2, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 273/425 reads (64%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 439/439 reads (100%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCA3 | c.478C>T p.R160W | Missense Mutation (SNP) | VAF 99/189 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); catalogued as rs778698150, COSV57055309; called by muse, mutect2, varscan2
- ACCS | c.1108C>T p.R370C | Missense Mutation (SNP) | VAF 234/410 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs765681909; called by muse, mutect2, varscan2
- APC | c.4308del p.S1436Rfs*37 | Frame Shift Del (DEL) | VAF 471/646 reads (73%) | catalogued as CD084027, COSV57331668; called by mutect2, pindel, varscan2
- AR | c.2440T>G p.F814V | Missense Mutation (SNP) | VAF 139/261 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV101017553, COSV65954499; called by muse, mutect2, varscan2
- BCL6B | c.461C>T p.T154M | Missense Mutation (SNP) | VAF 346/361 reads (96%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.474); catalogued as rs1311866828; called by muse, mutect2, varscan2
- C11orf87 | c.322G>A p.G108S | Missense Mutation (SNP) | VAF 379/597 reads (63%) | SIFT tolerated (0.75); PolyPhen benign (0.011); catalogued as COSV59358210; called by muse, mutect2, varscan2
- CAMTA1 | c.2507C>T p.S836L | Missense Mutation (SNP) | VAF 293/591 reads (50%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.006); catalogued as rs145537629; called by muse, mutect2, varscan2
- CLDN8 | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 136/291 reads (47%) | SIFT tolerated (0.26); PolyPhen benign (0.198); catalogued as rs757114600, COSV54525792; called by muse, mutect2, varscan2
- COL18A1 | c.2824C>T p.R942C (on ENST00000359759 / NM_130444.3; = p.R707C on NM_030582.4) | Missense Mutation (SNP) | VAF 172/399 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs771376510, COSV62698097; called by muse, mutect2, varscan2
- COL6A6 | c.2905G>A p.V969M | Missense Mutation (SNP) | VAF 629/630 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs530717316, COSV62020583; called by muse, mutect2, varscan2
- CPXM1 | c.1965G>A p.A655= | Splice Region (SNP) | VAF 304/463 reads (66%) | catalogued as rs770444464, COSV101013736; called by muse, mutect2, varscan2
- DLGAP4 | c.13G>A p.G5S | Missense Mutation (SNP) | VAF 452/1112 reads (41%) | SIFT tolerated (0.74); PolyPhen benign (0.005); catalogued as rs779644254, COSV100210688; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.2590C>T p.R864W | Missense Mutation (SNP) | VAF 890/891 reads (100%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.67); catalogued as rs201775833; called by muse, mutect2, varscan2
- FABP4 | c.326G>A p.R109Q | Missense Mutation (SNP) | VAF 177/179 reads (99%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs772636190; called by muse, mutect2, varscan2
- FTHL17 | c.29G>A p.R10H | Missense Mutation (SNP) | VAF 210/443 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as rs748357093, COSV63266985; called by muse, mutect2, varscan2
- GKN3P | c.40G>A p.V14I | Missense Mutation (SNP) | VAF 305/473 reads (64%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs1368668848; called by muse, mutect2, varscan2
- GPR139 | c.650G>A p.R217H | Missense Mutation (SNP) | VAF 76/168 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.961); catalogued as rs761772877, COSV58502353; called by muse, mutect2, varscan2
- ITGA4 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 155/256 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs890547243; called by muse, mutect2, varscan2
- ITPR1 | c.4757G>A p.R1586H (on ENST00000354582; = p.R1571H on NM_002222.7) | Missense Mutation (SNP) | VAF 401/402 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.618); catalogued as rs754960125; called by muse, mutect2, varscan2
- KCNA1 | c.596C>A p.T199K | Missense Mutation (SNP) | VAF 394/631 reads (62%) | SIFT tolerated (0.94); PolyPhen benign (0.001); catalogued as COSV66837998, COSV66838322; called by muse, mutect2, varscan2
- KIRREL1 | c.283G>A p.D95N | Missense Mutation (SNP) | VAF 212/660 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs779887253; called by muse, varscan2
- MATN4 | c.1450C>T p.R484W (on ENST00000372754; = p.R443W on NM_003833.4) | Missense Mutation (SNP) | VAF 239/1439 reads (17%) | PolyPhen probably damaging (1); catalogued as rs202220426; called by muse, mutect2, varscan2
- MROH9 | c.615C>T p.N205= | Splice Region (SNP) | VAF 188/265 reads (71%) | catalogued as rs199761702; called by muse, mutect2, varscan2
- MUC16 | c.37435G>A p.E12479K | Missense Mutation (SNP) | VAF 52/332 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.957); catalogued as COSV67467600; called by muse, mutect2, varscan2
- MYH14 | c.1450A>G p.I484V | Missense Mutation (SNP) | VAF 325/514 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV51826620; called by muse, mutect2, varscan2
- NDUFS7 | c.404G>A p.R135H | Missense Mutation (SNP) | VAF 294/879 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.945); catalogued as COSV99282653; called by muse, mutect2, varscan2
- NPEPL1 | c.1363G>A p.D455N | Missense Mutation (SNP) | VAF 179/1023 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.192); catalogued as rs753969799; called by muse, mutect2, varscan2
- PRICKLE1 | c.1952C>T p.P651L | Missense Mutation (SNP) | VAF 152/456 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750913400, COSV58209982; called by muse, mutect2, varscan2
- RGS7 | c.166G>A p.V56I | Missense Mutation (SNP) | VAF 100/179 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.106); catalogued as rs765729186, COSV58529676; called by muse, mutect2, varscan2
- RIPOR2 | c.2575C>T p.R859* | Nonsense Mutation (SNP) | VAF 174/174 reads (100%) | catalogued as rs1390766276, COSV52420109; called by muse, mutect2, varscan2
- RNF112 | c.1094G>A p.R365Q | Missense Mutation (SNP) | VAF 165/339 reads (49%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs777327708, COSV101465399, COSV99070945; called by muse, mutect2, varscan2
- RYR3 | c.854G>A p.R285Q | Missense Mutation (SNP) | VAF 314/314 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1164934345; called by muse, mutect2, varscan2
- SAFB | c.2072G>A p.R691H | Missense Mutation (SNP) | VAF 219/755 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs776169980; called by muse, mutect2, varscan2
- SHQ1 | c.478C>T p.R160W | Missense Mutation (SNP) | VAF 208/317 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764950055; called by muse, mutect2, varscan2
- SIRPA | c.721C>T p.R241C | Missense Mutation (SNP) | VAF 343/558 reads (61%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.92); catalogued as COSV100605219; called by muse, mutect2, varscan2
- SMAD3 | c.742T>A p.F248I | Missense Mutation (SNP) | VAF 436/438 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as CM145134; called by muse, mutect2, varscan2
- SUGP2 | c.2972G>A p.R991H | Missense Mutation (SNP) | VAF 273/444 reads (61%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.904); catalogued as rs752897249, COSV58266883; called by muse, mutect2, varscan2
- SYT4 | c.532C>T p.R178C | Missense Mutation (SNP) | VAF 327/327 reads (100%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.51); catalogued as rs754098951; called by muse, mutect2, varscan2
- TECTA | c.3851G>A p.R1284H | Missense Mutation (SNP) | VAF 387/624 reads (62%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.475); catalogued as rs141717375, COSV50694342; called by muse, mutect2, varscan2
- THSD7A | c.4765C>T p.R1589W | Missense Mutation (SNP) | VAF 122/427 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.821); catalogued as rs752652034, COSV101349199; called by muse, mutect2, varscan2
- TMEM178B | c.395G>A p.R132Q | Missense Mutation (SNP) | VAF 122/362 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as rs960934820, COSV73743798; called by muse, mutect2, varscan2
- VPS13D | c.1463C>T p.T488M | Missense Mutation (SNP) | VAF 138/344 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs980146059, COSV62524940; called by muse, mutect2, varscan2
- XKR7 | c.1510C>T p.R504W | Missense Mutation (SNP) | VAF 1127/1396 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs530229497, COSV73813066; called by muse, mutect2, varscan2
- ZFPM2 | c.2092C>T p.R698W | Missense Mutation (SNP) | VAF 335/715 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375403029, COSV101022963; called by muse, mutect2, varscan2
- ZNF185 | c.920C>T p.S307F | Missense Mutation (SNP) | VAF 319/319 reads (100%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.592); catalogued as rs1382092408; called by muse, mutect2, varscan2
- ABCA13 | c.1235C>A p.P412Q | Missense Mutation (SNP) | VAF 127/393 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.662); called by muse, mutect2, varscan2
- AKR1B15 | c.194A>T p.D65V | Missense Mutation (SNP) | VAF 46/358 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); called by mutect2, varscan2
- ANKAR | c.170C>G p.A57G | Missense Mutation (SNP) | VAF 312/502 reads (62%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARFGAP1 | c.922G>A p.G308S | Missense Mutation (SNP) | VAF 151/704 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ARSL | c.1575C>G p.I525M | Missense Mutation (SNP) | VAF 207/485 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- ATP8A2 | c.362T>A p.L121Q | Missense Mutation (SNP) | VAF 57/187 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C10orf90 | c.1618G>A p.A540T | Missense Mutation (SNP) | VAF 375/375 reads (100%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.509); called by muse, mutect2, varscan2
- CD93 | c.777C>A p.S259R | Missense Mutation (SNP) | VAF 197/1241 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CEL | c.835del p.Q279Sfs*3 (on ENST00000673714; = p.Q276Sfs*3 on NM_001807.6) | Frame Shift Del (DEL) | VAF 285/552 reads (52%) | called by mutect2, pindel, varscan2
- CEPT1 | c.458T>G p.F153C | Missense Mutation (SNP) | VAF 90/186 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHD5 | c.1877T>A p.I626N | Missense Mutation (SNP) | VAF 195/438 reads (45%) | SIFT tolerated (0.47); PolyPhen benign (0.239); called by muse, mutect2, varscan2
- CNTNAP4 | c.1184C>A p.T395N | Missense Mutation (SNP) | VAF 172/365 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- CREG1 | c.619A>T p.K207* | Nonsense Mutation (SNP) | VAF 87/346 reads (25%) | called by muse, mutect2, varscan2
- CUX2 | c.2676G>T p.M892I | Missense Mutation (SNP) | VAF 252/812 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- CYFIP1 | c.3751G>T p.A1251S | Missense Mutation (SNP) | VAF 211/211 reads (100%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- DCAF12L2 | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 602/602 reads (100%) | SIFT tolerated (0.23); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- DYRK3 | c.214G>T p.D72Y | Missense Mutation (SNP) | VAF 114/372 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- EPHB1 | c.2209G>A p.E737K | Missense Mutation (SNP) | VAF 159/801 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- FRAT1 | c.361G>A p.V121M | Missense Mutation (SNP) | VAF 627/628 reads (100%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- FSHR | c.163C>T p.L55F | Missense Mutation (SNP) | VAF 155/245 reads (63%) | SIFT tolerated (0.69); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- GNL3 | c.121C>T p.H41Y | Missense Mutation (SNP) | VAF 429/429 reads (100%) | SIFT tolerated (0.79); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- ITIH6 | c.2602A>G p.S868G | Missense Mutation (SNP) | VAF 227/527 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- KRBA1 | c.1255A>G p.R419G | Missense Mutation (SNP) | VAF 176/515 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRIF1 | c.377G>A p.G126E | Missense Mutation (SNP) | VAF 84/167 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MANEA | c.539C>A p.S180* | Nonsense Mutation (SNP) | VAF 132/132 reads (100%) | called by muse, mutect2, varscan2
- MAP3K19 | c.596A>T p.K199M | Missense Mutation (SNP) | VAF 119/207 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- MYO19 | c.245C>T p.P82L | Missense Mutation (SNP) | VAF 211/415 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.645); called by muse, mutect2, varscan2
- NEXMIF | c.2945C>T p.P982L | Missense Mutation (SNP) | VAF 186/438 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NFASC | c.2702G>A p.S901N (on ENST00000339876 / NM_001378329.1; = p.S1004N on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 111/647 reads (17%) | SIFT tolerated (0.61); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- NPL | c.22C>A p.L8I | Missense Mutation (SNP) | VAF 274/430 reads (64%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- NXT2 | c.184_185insG p.F62Cfs*3 (on ENST00000372106 / NM_001242617.2; = p.F117Cfs*3 on NM_018698.5) | Frame Shift Ins (INS) | VAF 97/293 reads (33%) | called by mutect2, pindel, varscan2
- OR52E4 | c.143T>C p.L48P | Missense Mutation (SNP) | VAF 184/305 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- OTOGL | c.6533C>A p.P2178Q (on ENST00000547103; = p.P2169Q on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/385 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2
- OVGP1 | c.1319A>G p.E440G | Missense Mutation (SNP) | VAF 131/297 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- OVGP1 | c.1318G>T p.E440* | Nonsense Mutation (SNP) | VAF 133/299 reads (44%) | called by muse, mutect2, varscan2
- PAMR1 | c.1946G>C p.C649S (on ENST00000619888 / NM_001001991.3; = p.C666S on NM_015430.4) | Missense Mutation (SNP) | VAF 375/613 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PBRM1 | c.392C>T p.S131F | Missense Mutation (SNP) | VAF 23/382 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- PIM2 | c.250G>C p.V84L | Missense Mutation (SNP) | VAF 320/320 reads (100%) | SIFT tolerated (0.15); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- POSTN | c.2120G>T p.G707V | Missense Mutation (SNP) | VAF 85/260 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PPIAL4A | c.80A>G p.D27G | Missense Mutation (SNP) | VAF 224/524 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- PUM1 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 136/251 reads (54%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- PYROXD1 | c.1038G>C p.M346I | Missense Mutation (SNP) | VAF 226/372 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2
- RPS27AP5 | c.81G>T p.K27N | Missense Mutation (SNP) | VAF 137/461 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- SERPINB7 | c.627T>G p.H209Q | Missense Mutation (SNP) | VAF 12/290 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.897); called by muse, mutect2
- SOX18 | c.625G>A p.G209S | Missense Mutation (SNP) | VAF 377/1930 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- SPEG | c.8738del p.P2913Lfs*15 | Frame Shift Del (DEL) | VAF 163/509 reads (32%) | called by mutect2, pindel, varscan2
- SPTLC3 | c.111del p.A38Pfs*46 | Frame Shift Del (DEL) | VAF 82/317 reads (26%) | called by mutect2, pindel, varscan2
- SRD5A2 | c.202C>A p.L68I | Missense Mutation (SNP) | VAF 787/1142 reads (69%) | SIFT tolerated (0.15); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- STARD9 | c.10880G>A p.G3627D | Missense Mutation (SNP) | VAF 432/433 reads (100%) | SIFT tolerated (0.3); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- STXBP5L | c.3512C>T p.A1171V | Missense Mutation (SNP) | VAF 198/420 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- TDRD15 | c.494T>G p.F165C | Missense Mutation (SNP) | VAF 124/195 reads (64%) | SIFT deleterious (0.01); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- TNR | c.1296G>T p.E432D | Missense Mutation (SNP) | VAF 199/331 reads (60%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TTC1 | c.856C>G p.Q286E | Missense Mutation (SNP) | VAF 74/274 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TTN | c.19485A>C p.K6495N (on ENST00000591111; = p.K5568N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 352/528 reads (67%) | PolyPhen benign (0.007); called by muse, mutect2, varscan2
- USP34 | c.2599G>C p.V867L | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated (0.99); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- WDR81 | c.2906C>A p.A969D | Missense Mutation (SNP) | VAF 366/707 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- ZFYVE28 | c.235C>T p.R79C | Missense Mutation (SNP) | VAF 324/324 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNFX1 | c.1804C>A p.Q602K | Missense Mutation (SNP) | VAF 286/798 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANKRD20A4P | c.1827T>C p.Y609= | Silent (SNP) | VAF 177/842 reads (21%) | called by muse, mutect2, varscan2
- ATMIN | c.1338G>A p.S446= | Silent (SNP) | VAF 219/284 reads (77%) | catalogued as rs371161001; called by muse, mutect2, varscan2
- CATSPERG | c.579C>A p.T193= | Silent (SNP) | VAF 138/398 reads (35%) | called by muse, mutect2, varscan2
- CCDC27 | c.849C>T p.S283= | Silent (SNP) | VAF 114/244 reads (47%) | called by muse, mutect2, varscan2
- CRB1 | c.2068T>C p.L690= | Silent (SNP) | VAF 156/470 reads (33%) | called by muse, mutect2, varscan2
- CYLC1 | c.460A>C p.R154= | Silent (SNP) | VAF 33/84 reads (39%) | called by muse, mutect2, varscan2
- DNM1L | c.708A>T p.P236= | Silent (SNP) | VAF 100/318 reads (31%) | catalogued as COSV56774353; called by muse, mutect2, varscan2
- DRD2 | c.648C>G p.L216= | Silent (SNP) | VAF 311/488 reads (64%) | catalogued as COSV100670103; called by muse, mutect2, varscan2
- EDC4 | c.18C>T p.S6= | Silent (SNP) | VAF 238/462 reads (52%) | called by muse, mutect2, varscan2
- EME2 | c.261C>T p.D87= | Silent (SNP) | VAF 228/359 reads (64%) | called by muse, mutect2, varscan2
- FER1L6 | c.510C>T p.T170= | Silent (SNP) | VAF 248/584 reads (42%) | catalogued as rs368650874; called by muse, mutect2, varscan2
- INTS5 | c.1767C>T p.G589= | Silent (SNP) | VAF 441/667 reads (66%) | catalogued as rs562972467; called by muse, mutect2, varscan2
- LELP1 | c.6G>A p.S2= | Silent (SNP) | VAF 98/332 reads (30%) | catalogued as rs771068500, COSV64202288; called by muse, mutect2, varscan2
- MATN4 | c.510G>A p.A170= | Silent (SNP) | VAF 146/1624 reads (9%) | catalogued as COSV100637192; called by muse, mutect2
- MEPCE | c.1839G>A p.L613= | Silent (SNP) | VAF 188/595 reads (32%) | called by muse, mutect2, varscan2
- MUC5B | c.5862T>G p.T1954= | Silent (SNP) | VAF 343/1103 reads (31%) | called by muse, mutect2, varscan2
- MYOD1 | c.246C>T p.R82= | Silent (SNP) | VAF 350/1098 reads (32%) | catalogued as rs756383719, COSV100000238; called by muse, mutect2, varscan2
- NRK | c.2322A>G p.P774= | Silent (SNP) | VAF 11/199 reads (6%) | called by muse, mutect2
- OR2A7 | c.204C>T p.V68= | Silent (SNP) | VAF 123/959 reads (13%) | catalogued as rs764358983, COSV101512182; called by muse, mutect2
- OTOGL | c.2175C>T p.C725= (on ENST00000547103; = p.C716= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 162/493 reads (33%) | catalogued as rs940673548, COSV72006129; called by muse, mutect2, varscan2
- PCDHGA6 | c.1908C>T p.D636= | Silent (SNP) | VAF 631/631 reads (100%) | catalogued as rs770239249, COSV53896503; called by muse, mutect2, varscan2
- PLXNA3 | c.3249C>T p.G1083= | Silent (SNP) | VAF 520/522 reads (100%) | catalogued as rs1557207502; called by muse, mutect2, varscan2
- PROP1 | c.282C>T p.P94= | Silent (SNP) | VAF 542/546 reads (99%) | catalogued as rs776294029; called by muse, mutect2, varscan2
- SCN1A | c.2658C>T p.S886= (on ENST00000303395 / NM_001202435.3; = p.S875= on NM_006920.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 257/379 reads (68%) | catalogued as rs776714907, COSV57660002; called by muse, mutect2, varscan2
- SKOR1 | c.1965C>T p.T655= | Silent (SNP) | VAF 758/761 reads (100%) | catalogued as rs1039482021; called by muse, mutect2, varscan2
- SLC9A7 | c.6G>A p.E2= | Silent (SNP) | VAF 196/447 reads (44%) | called by muse, mutect2, varscan2
- SLCO2A1 | c.1819C>T p.L607= | Silent (SNP) | VAF 46/426 reads (11%) | called by muse, mutect2
- STRIP2 | c.114G>A p.Q38= | Silent (SNP) | VAF 174/595 reads (29%) | called by muse, mutect2, varscan2
- TRIM58 | c.408C>T p.A136= | Silent (SNP) | VAF 124/544 reads (23%) | called by muse, mutect2, varscan2
- ZAN | c.3528C>T p.G1176= | Silent (SNP) | VAF 28/514 reads (5%) | catalogued as rs377076232; called by muse, mutect2
- ZCCHC14 | c.18G>T p.P6= (on ENST00000268616; = p.P143= on NM_015144.3) | Silent (SNP) | VAF 33/454 reads (7%) | catalogued as rs766145058; called by muse, mutect2
- ZP2 | c.2109C>T p.T703= | Silent (SNP) | VAF 60/154 reads (39%) | called by muse, mutect2, varscan2
- AC084740.1 | n.774del | RNA (DEL) | VAF 71/275 reads (26%) | called by mutect2, pindel, varscan2
- ATXN8OS | n.499+993_499+995del | Intron (DEL) | VAF 85/240 reads (35%) | called by pindel, varscan2
- SEPTIN4 | c.797+33C>A | Intron (SNP) | VAF 167/345 reads (48%) | called by muse, mutect2, varscan2
- UMODL1 | c.1899+189G>A | Intron (SNP) | VAF 402/981 reads (41%) | catalogued as rs542395191; called by muse, mutect2
